CPTAC case C3L-00771 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/074c8f3c-b4aa-4c10-ba83-2a874f88c478

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1929; Vital status: Dead; Days to death: 134 days; Year of death: 2016; Cause of death: Cardiovascular Disorder, NOS.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 86.7 years (31,649 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 134 days; Days to last follow up: 134 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 6 cm (a second GDC size field records 3.1 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 134 days; Karnofsky performance status: 0; ECOG performance status: 4.

Other clinical attributes
- Weight: 56.7 kg; Height: 157.48 cm; BMI: 22.86; Comorbidities: Tuberculosis.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00771-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 121 days; Initial weight: 220 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00771-21: Section location: Posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-00771-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 121 days; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3L-00771-31, C3L-00771-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3L-00771-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 121 days; Method of sample procurement: Blood Draw.
